Somatic mutation profile of tumor specimen MP2PRT-PAUGAW-TMP1-A (aliquot MP2PRT-PAUGAW-TMP1-A-1-0-D-A82L-36) from MP2PRT case MP2PRT-PAUGAW, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.4 years (1,619 days).
Specimen MP2PRT-PAUGAW-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7dcc03cd-0c04-47ca-8c3a-782043e0e72c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAUGAW-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAUGAW-NB1-A-1-0-D-A82L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e794a596-2e1f-4921-86f5-a6c5259ae242

The open-access MAF lists 23 somatic variants for this specimen: 20 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 19, Silent 2, Intron 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SF3B1 | c.1998G>C p.K666N | Missense Mutation (SNP) | VAF 34/488 reads (7%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs377023736, COSV59205777, COSV59205799; ClinVar: likely pathogenic; called by muse, mutect2
- CYP11A1 | c.85C>T p.R29C | Missense Mutation (SNP) | VAF 27/649 reads (4%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs748686615; called by muse, mutect2
- KCNJ3 | c.206C>T p.S69L | Missense Mutation (SNP) | VAF 157/440 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as COSV54533558, COSV99715872; called by muse, mutect2, varscan2
- MID1 | c.1894G>A p.A632T | Missense Mutation (SNP) | VAF 168/256 reads (66%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs747547954, COSV58197212; called by muse, mutect2, varscan2
- PRR14L | c.3390dup p.S1131Ifs*3 | Frame Shift Ins (INS) | VAF 92/248 reads (37%) | catalogued as rs759511927; called by mutect2, varscan2
- SPIRE1 | c.2255C>T p.T752M (on ENST00000409402 / NM_001128626.2; = p.T738M on NM_020148.3) | Missense Mutation (SNP) | VAF 64/225 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.917); catalogued as rs761806323, COSV59156058; called by muse, mutect2, varscan2
- SYNE1 | c.4000C>T p.R1334C (on ENST00000367255 / NM_182961.4; = p.R1341C on NM_033071.3) | Missense Mutation (SNP) | VAF 29/390 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.719); catalogued as rs754120599; ClinVar: uncertain significance; called by muse, mutect2
- VIL1 | c.1052C>T p.A351V | Missense Mutation (SNP) | VAF 176/502 reads (35%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs765832052; called by muse, mutect2, varscan2
- VPS18 | c.476C>T p.P159L | Missense Mutation (SNP) | VAF 34/592 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.441); catalogued as COSV99592396; called by muse, mutect2
- AFAP1L1 | c.741G>T p.Q247H | Missense Mutation (SNP) | VAF 14/294 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); called by muse, mutect2
- AHNAK | c.6079G>A p.G2027R | Missense Mutation (SNP) | VAF 75/455 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.117); called by muse, mutect2, varscan2
- BUB1 | c.1576G>T p.A526S | Missense Mutation (SNP) | VAF 18/312 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.143); called by muse, mutect2
- CANT1 | c.1016T>G p.V339G | Missense Mutation (SNP) | VAF 22/628 reads (4%) | SIFT tolerated (0.46); PolyPhen benign (0.003); called by muse, mutect2
- CDC42EP2 | c.371C>T p.A124V | Missense Mutation (SNP) | VAF 213/683 reads (31%) | SIFT tolerated (0.26); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- LRRTM3 | c.1555G>C p.V519L | Missense Mutation (SNP) | VAF 82/218 reads (38%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0); called by muse, mutect2, varscan2
- MED23 | c.2377C>T p.L793F | Missense Mutation (SNP) | VAF 94/281 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- MMP13 | c.874G>T p.A292S | Missense Mutation (SNP) | VAF 16/345 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); called by muse, mutect2
- PCDH18 | c.1261G>T p.A421S | Missense Mutation (SNP) | VAF 20/216 reads (9%) | SIFT tolerated (0.6); PolyPhen benign (0.026); called by muse, mutect2
- TNXB | c.8290C>A p.P2764T (on ENST00000647633; = p.P2517T on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/470 reads (4%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); called by muse, mutect2
- ZNF248 | c.1289A>C p.H430P | Missense Mutation (SNP) | VAF 130/456 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DNAH7 | c.3381C>T p.L1127= | Silent (SNP) | VAF 25/460 reads (5%) | catalogued as rs1360565564; called by muse, mutect2
- LMOD2 | c.792C>G p.L264= | Silent (SNP) | VAF 14/498 reads (3%) | called by muse, mutect2
- NPIPA5 | c.642+168A>G | Intron (SNP) | VAF 108/469 reads (23%) | called by muse, varscan2
